Gene-level copy-number profile of tumor specimen C3L-04236-54 from CPTAC case C3L-04236, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 70.0 years (25,568 days).
Specimen C3L-04236-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3da67957-3bf7-4f15-99ef-2476e1a8c58f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04236-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/fd208044-7c4b-4b24-9e27-03e7280cba33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 270; copy number 2: 57,651; copy number 3: 457; copy number 5: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr16:46,469,341–46,575,094, 4 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
